Gene-level copy-number profile of tumor specimen TCGA-B6-A0WX-01A from TCGA case TCGA-B6-A0WX, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 40.5 years (14,784 days).
Specimen TCGA-B6-A0WX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.b0c0bc65-5f9b-4f23-a1c9-e3f86c0ef65c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0WX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/716db2b2-4f43-4e3e-8f0e-9c7a3bfb13b6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 2: 20,756; copy number 3: 2,880; copy number 4: 22,963; copy number 5: 5,130; copy number 6: 1,920; copy number 7: 1,137; copy number 8: 195; copy number 9: 2,054; copy number 10: 24; copy number 11: 3; copy number 12: 2,607; copy number 13: 18; copy number 14: 125; copy number 18: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A0WX-01A-11D-A107-01): tumor purity 0.34, ploidy 3.78, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:77,775,783–77,783,576, 1 gene: AC138331.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13,215 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:35,869,808–101,390,303, 1,295 genes, copy number 5–9 (broad region; genes not listed).
- chr1:115,556,826–248,919,946, 2,746 genes, copy number 7–14 (broad region; genes not listed).
- chr2:80,288,351–80,870,190, 3 genes, copy number 11 (within-gene range 4–11): LRRTM1, AC008067.1, AC012355.1.
- chr2:94,725,674–96,552,634, 86 genes, copy number 7 (broad region; genes not listed).
- chr8:31,639,222–32,855,666, 1 gene, copy number 10 (within-gene range 2–10): NRG1.
- chr8:32,026,210–33,580,508, 23 genes, copy number 10: NRG1-IT1, RNA5SP262, RNA5SP263, NRG1-IT3, AC083977.1, RNU6-663P, AC090204.1, MTND1P6, MTND2P32, RANP9, AC104027.1, RNU6-528P, AC067838.1, FUT10, AC091144.2, TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P.
- chr8:34,784,028–40,016,391, 105 genes, copy number 8 (broad region; genes not listed).
- chr8:40,519,565–145,066,685, 1,618 genes, copy number 7–9 (broad region; genes not listed).
- chr11:31,509,755–32,104,665, 5 genes, copy number 8–18 (within-gene range 2–18): ELP4, AC131571.1, PAX6, PAUPAR, AL035078.4.
- chr11:34,049,967–34,663,288, 13 genes, copy number 9 (within-gene range 2–9): AC090469.1, CAPRIN1, NAT10, ABTB2, Y_RNA, MMADHCP2, AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF.
- chr11:43,827,517–46,594,125, 69 genes, copy number 6–9 (within-gene range 2–9) (broad region; genes not listed).
- chr12:46,183,063–46,972,155, 13 genes, copy number 7: SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1.
- chr12:58,244,378–58,395,138, 2 genes, copy number 14: RPL21P103, AC025578.1.
- chr12:59,322,765–59,450,772, 4 genes, copy number 14 (within-gene range 4–14): AC108721.2, AC108721.1, RNU6-279P, RNU6-871P.
- chr12:68,674,371–70,637,440, 47 genes, copy number 9–13: AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1.
- chr12:84,448,625–84,449,878, 1 gene, copy number 12: AC087888.1.
- chr12:87,169,985–87,820,918, 8 genes, copy number 13: RPL23AP68, AC079598.4, CYCSP30, AC079598.2, MKRN9P, LINC02258, AC079598.1, AC079598.3.
- chr12:89,010,681–89,309,566, 2 genes, copy number 12 (within-gene range 2–12): LINC02458, AC006199.1.
- chr13:81,114,866–81,302,407, 5 genes, copy number 6: DPPA3P3, LINC00564, AL353633.1, RNU6-77P, HIGD1AP2.
- chr15:19,878,555–29,118,315, 360 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr16:11,555–66,613,892, 1,835 genes, copy number 5 (broad region; genes not listed).
- chr16:70,802,084–71,230,722, 4 genes, copy number 8 (within-gene range 4–8): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.
- chr17:142,789–83,095,122, 3,047 genes, copy number 5–7 (broad region; genes not listed).
- chr19:94,062–29,824,312, 1,346 genes, copy number 5–6 (broad region; genes not listed).
- chr20:5,292,388–6,780,246, 36 genes, copy number 9: UBE2D3P1, PROKR2, AL121757.2, RNA5-8SP7, AL121757.3, LINC00658, AL121757.1, LINC00654, LINC01729, RPS18P1, AL109935.1, GPCPD1, EIF4EP1, SHLD1, RNU1-55P, CHGB, KANK1P1, TRMT6, MCM8, AL035461.3, Y_RNA, AL035461.1, MCM8-AS1, AL035461.2, RN7SL498P, CRLS1, LRRN4, AL118505.1, FERMT1, TARDBPP1, AL109618.1, AL109618.2, AL109618.3, CASC20, LINC01713, BMP2.
- chr20:7,633,562–10,434,222, 34 genes, copy number 6–9: RN7SL547P, AL031679.1, AL021879.1, HAO1, TMX4, AL021396.1, PLCB1, PHKBP1, PLCB1-IT1, RNU105B, AL445567.1, AL445567.2, Metazoa_SRP, PLCB4, LAMP5-AS1, LAMP5, PAK5, AL353612.2, AL353612.1, AL034427.1, PARAL1, ANKEF1, SNAP25-AS1, Metazoa_SRP, AL354824.1, AL354824.2, SNAP25, AL023913.1, HIGD1AP15, RPL23AP6, SDAD1P2, MKKS, AL034430.1, AL034430.2.
- chr20:13,995,369–16,053,197, 1 gene, copy number 7 (within-gene range 2–7): MACROD2.
- chr20:14,547,184–34,927,962, 423 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr21:10,328,411–15,880,069, 83 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
